Somatic mutation profile of tumor specimen TCGA-DD-A39Y-01A (aliquot TCGA-DD-A39Y-01A-11D-A20W-10) from TCGA case TCGA-DD-A39Y, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 67.8 years (24,769 days).
Specimen TCGA-DD-A39Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b6e589e-2154-481f-9f38-6e3bbb1cb5c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A39Y-11A (Solid Tissue Normal), aliquot TCGA-DD-A39Y-11A-11D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44189b6f-92fe-479e-a474-ce8739768550

The open-access MAF lists 352 somatic variants for this specimen: 329 protein-altering or splice-affecting, 10 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 305, Missense Mutation 17, Silent 10, Splice Site 6, Intron 6, 3'UTR 3, RNA 2, 5'Flank 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP290 | c.3175del p.I1059* | Frame Shift Del (DEL) | VAF 13/98 reads (13%) | catalogued as rs62640570, CD073593; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FBN1 | c.7780del p.Q2594Rfs*88 | Frame Shift Del (DEL) | VAF 8/95 reads (8%) | catalogued as rs1555394146, CD098518; ClinVar: pathogenic; called by mutect2, pindel
- TBX5 | c.1158del p.S387Afs*7 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | catalogued as rs1064795870; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- ACSM4 | c.14del p.F5Sfs*29 | Frame Shift Del (DEL) | VAF 8/100 reads (8%) | catalogued as rs1435243274; called by mutect2, pindel
- ADAMTS18 | c.3125G>T p.G1042V | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV51399220; called by muse, mutect2, varscan2
- ADCY7 | c.1477del p.A493Rfs*14 | Frame Shift Del (DEL) | VAF 10/89 reads (11%) | catalogued as rs1259233981; called by mutect2, pindel, varscan2
- ADSS1 | c.741del p.K248Rfs*23 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | catalogued as rs769542442; called by pindel, varscan2
- AFF2 | c.2076del p.E693Rfs*62 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | catalogued as COSV54011824; called by mutect2, pindel
- AICDA | c.476del p.F159Sfs*51 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | catalogued as rs1565509169; called by mutect2, pindel
- APMAP | c.328+1del p.X110_splice | Splice Site (DEL) | VAF 8/81 reads (10%) | catalogued as rs754512895; called by mutect2, pindel
- ATP2A3 | c.732del p.E245Sfs*22 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | catalogued as COSV99988945; called by mutect2, pindel
- BMP15 | c.911del p.G304Vfs*66 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | catalogued as COSV99399448; called by mutect2, pindel
- CBR4 | c.145del p.D49Ifs*26 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as COSV60369856; called by mutect2, pindel
- CCDC136 | c.3085A>C p.K1029Q | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV52796413; called by mutect2, varscan2
- CLEC12A | c.649del p.R217Efs*6 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | catalogued as COSV58560932; called by mutect2, pindel
- COG4 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs1182349075, COSV60421344; called by muse, varscan2
- CPPED1 | c.44del p.G15Afs*31 | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | catalogued as rs759977975; called by mutect2, pindel
- DAP | c.21del p.K8Nfs*2 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | catalogued as rs1160193788; called by mutect2, pindel
- DCX | c.936C>A p.N312K | Missense Mutation (SNP) | VAF 64/97 reads (66%) | SIFT tolerated (0.96); PolyPhen benign (0.089); catalogued as COSV100576807, COSV57566222; called by mutect2, varscan2
- DDX43 | c.24del p.K9Rfs*27 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | catalogued as COSV64836437; called by mutect2, pindel
- DDX60L | c.3537del p.V1180Cfs*13 | Frame Shift Del (DEL) | VAF 23/220 reads (10%) | catalogued as rs749766723; called by mutect2, pindel
- DHX16 | c.1681del p.S561Pfs*36 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | catalogued as COSV64563593; called by mutect2, pindel
- DIP2C | c.1875del p.W626Gfs*58 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | catalogued as COSV55159383; called by mutect2, pindel
- DISP1 | c.3232C>A p.R1078S | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV52655046, COSV52655692; called by mutect2, varscan2
- DNLZ | c.465del p.T156Hfs*134 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | catalogued as rs1333961482; called by pindel, varscan2
- ERG | c.1397del p.G466Vfs*46 (on ENST00000398919 / NM_001243428.1; = p.G442Vfs*46 on NM_004449.4) | Frame Shift Del (DEL) | VAF 14/152 reads (9%) | catalogued as COSV55739379; called by mutect2, pindel
- FAM222B | c.719del p.P240Rfs*3 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | catalogued as COSV100368550, COSV100368697; called by mutect2, pindel
- FBXO5 | c.1017del p.D340Mfs*30 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | catalogued as rs1292004982; called by mutect2, varscan2
- GALNT16 | c.583del p.R195Efs*22 | Frame Shift Del (DEL) | VAF 8/91 reads (9%) | catalogued as COSV61887891; called by mutect2, pindel
- GLI2 | c.845+1del | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | catalogued as COSV58033970; called by mutect2, pindel
- GPR155 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as rs775924682, COSV55037542; called by mutect2, varscan2
- GUCY2C | c.2270del p.N757Mfs*8 | Frame Shift Del (DEL) | VAF 9/92 reads (10%) | catalogued as COSV53791141; called by pindel, varscan2
- HHIP | c.2047del p.D683Ifs*6 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | catalogued as COSV56844374; called by mutect2, pindel
- HIC1 | c.2052del p.K685Rfs*28 (on ENST00000322941 / NM_001098202.1; = p.K666Rfs*28 on NM_006497.4) | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | catalogued as rs1318627856; called by mutect2, pindel
- HK3 | c.2158del p.D720Tfs*31 | Frame Shift Del (DEL) | VAF 15/170 reads (9%) | catalogued as COSV99458474; called by mutect2, pindel
- INO80D | c.1540del p.M514Wfs*5 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | catalogued as COSV68960008; called by mutect2, varscan2
- KDM6B | c.2226del p.T743Pfs*39 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as COSV54686166; called by mutect2, pindel
- LCOR | c.2644del p.D882Tfs*31 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | catalogued as COSV53714344; called by mutect2, pindel
- MASP1 | c.1916del p.K639Rfs*13 | Frame Shift Del (DEL) | VAF 8/93 reads (9%) | catalogued as rs754625392; called by mutect2, pindel
- MNDA | c.310del p.I104* | Frame Shift Del (DEL) | VAF 12/113 reads (11%) | catalogued as rs751496931; called by mutect2, pindel, varscan2
- MRPS5 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55532701; called by mutect2, varscan2
- OSBPL6 | c.1160C>G p.S387C | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as COSV51911486, COSV51923185; called by mutect2, varscan2
- PAK4 | c.565del p.Q189Sfs*180 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | catalogued as rs1217359611; called by pindel, varscan2
- PCARE | c.3248del p.P1083Lfs*30 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | catalogued as rs754349082; called by mutect2, pindel
- PCF11 | c.1754T>C p.V585A | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV53527921, COSV53537035; called by mutect2, varscan2
- PLA2G12B | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV65978239; called by muse, varscan2
- PLA2G3 | c.59del p.G20Afs*14 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | catalogued as COSV53207922; called by mutect2, pindel
- PNPLA2 | c.798del p.A267Pfs*53 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | catalogued as CM108998; called by mutect2, pindel
- PRAME | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV67161015; called by muse, mutect2, varscan2
- PUM1 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs551662997, COSV57081720; called by mutect2, varscan2
- SAP130 | c.2094G>T p.M698I | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV52094506; called by mutect2, varscan2
- SCAP | c.1373del p.P458Lfs*23 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | catalogued as COSV55562334; called by mutect2, pindel
- SEMA3D | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs1038960034, COSV52388038; called by mutect2, varscan2
- SERPINB5 | c.389del p.G130Vfs*19 | Frame Shift Del (DEL) | VAF 6/74 reads (8%) | catalogued as COSV66975315; called by mutect2, pindel
- SETD1A | c.1774G>A p.G592S | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.12); catalogued as COSV52685206; called by muse, varscan2
- SFTPB | c.1093del p.V365Cfs*39 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | catalogued as rs1558572460; called by mutect2, pindel
- SPATA31E1 | c.2691del p.K897Nfs*20 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | catalogued as COSV57789408; called by mutect2, pindel
- SRA1 | c.183del p.R62Efs*49 | Frame Shift Del (DEL) | VAF 12/152 reads (8%) | catalogued as rs1392118104; called by mutect2, pindel
- TCIM | c.259del p.R87Gfs*10 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | catalogued as COSV59928433; called by mutect2, pindel
- TP73 | c.1004del p.P335Lfs*10 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | catalogued as COSV104414957; called by pindel, varscan2
- TTN | c.77977A>G p.T25993A (on ENST00000591111; = p.T18569A on NM_003319.4) | Missense Mutation (SNP) | VAF 88/286 reads (31%) | PolyPhen benign (0.342); catalogued as COSV59901878; called by mutect2, varscan2
- WDR74 | c.67del p.V23* | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | catalogued as rs759766180; called by mutect2, pindel
- ZBTB14 | c.882G>T p.K294N | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.575); catalogued as COSV63696259; called by mutect2, varscan2
- ZNF428 | c.320del p.G107Efs*127 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | catalogued as rs1458759252; called by mutect2, pindel
- ZNF540 | c.843del p.F281Lfs*4 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | catalogued as rs757107073, COSV57110076; called by pindel, varscan2
- AAK1 | c.14del p.F5Sfs*59 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- AASDH | c.1733del p.D578Vfs*6 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- ABCG1 | c.1527del p.Q510Rfs*15 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by mutect2, pindel
- ABHD12B | c.834del p.D279Tfs*3 (on ENST00000337334 / NM_001206673.2; = p.D202Tfs*3 on NM_181533.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/113 reads (10%) | called by mutect2, pindel
- ACO2 | c.92del p.K31Rfs*4 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- ADAM8 | c.2345del p.P782Qfs*27 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- ADAMTS8 | c.2041del p.V681Cfs*38 | Frame Shift Del (DEL) | VAF 8/104 reads (8%) | called by mutect2, pindel
- ADAMTSL3 | c.2290del p.H764Tfs*27 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- ADH6 | c.72del p.I24Mfs*4 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- AKAP12 | c.634del p.A212Lfs*32 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel
- ALPK1 | c.3420del p.K1140Nfs*9 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- ANGPTL6 | c.966del p.P323Qfs*15 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- ANKRD50 | c.2897del p.L966* | Frame Shift Del (DEL) | VAF 16/179 reads (9%) | called by mutect2, pindel
- ANO3 | c.1343del p.N448Tfs*16 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- AP3D1 | c.1741del p.H581Tfs*24 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- APBA3 | c.1180del p.E394Rfs*51 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- APOE | c.56del p.K19Rfs*60 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- APPBP2 | c.276del p.V93Lfs*16 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- ARHGAP31 | c.2798del p.G933Afs*23 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by mutect2, pindel
- ARL6IP1 | c.399del p.K133Nfs*7 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- ARSJ | c.1082del p.S361Tfs*4 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- ATF3 | c.234del p.A79Pfs*3 | Frame Shift Del (DEL) | VAF 13/147 reads (9%) | called by mutect2, pindel
- ATM | c.2275del p.S759Vfs*18 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- ATP1B4 | c.150del p.K50Nfs*40 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- ATP6AP1 | c.1207del p.Q403Rfs*5 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- ATP6V1E1 | c.11del p.S4Tfs*9 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- ATP8B3 | c.2704del p.L902Wfs*13 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- ATRNL1 | c.3885del p.L1296Cfs*5 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- BPIFC | c.706del p.S236Lfs*11 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- BRS3 | c.1146del p.S383Vfs*2 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- C10orf88 | c.455del p.G152Afs*15 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- C1D | c.415del p.S139Vfs*42 | Frame Shift Del (DEL) | VAF 12/156 reads (8%) | called by mutect2, pindel
- C1GALT1C1 | c.77del p.G26Dfs*28 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- C1orf35 | c.443del p.F148Sfs*6 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- C20orf141 | c.488del p.P163Lfs*? | Frame Shift Del (DEL) | VAF 4/49 reads (8%) | called by mutect2, pindel
- C6orf120 | c.338del p.P113Qfs*19 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel
- CACNA1F | c.2373del p.G792Vfs*69 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- CAPN7 | c.766del p.T256Lfs*18 | Frame Shift Del (DEL) | VAF 18/200 reads (9%) | called by mutect2, pindel, varscan2
- CARD8 | c.754del p.H252Tfs*47 (on ENST00000651546 / NM_001184900.3; = p.H202Tfs*47 on NM_014959.5 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- CARMIL1 | c.3623del p.G1208Efs*94 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- CARMIL2 | c.1253del p.P418Rfs*94 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- CBLB | c.558del p.F186Lfs*31 | Frame Shift Del (DEL) | VAF 9/86 reads (10%) | called by mutect2, pindel
- CBLC | c.366del p.K123Sfs*156 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | called by mutect2, pindel
- CBY2 | c.1114del p.E372Rfs*35 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- CCT6B | c.46del p.A16Pfs*29 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- CDH23 | c.8147del p.D2716Vfs*8 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- CDK13 | c.2501del p.L834Cfs*12 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- CEP162 | c.3588del p.K1196Nfs*5 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | called by mutect2, pindel
- CEP85L | c.1613del p.N538Ifs*8 | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | called by mutect2, pindel, varscan2
- CEP89 | c.1991del p.K664Sfs*34 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- CFAP77 | c.448del p.H150Tfs*3 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- CHGB | c.1213del p.S405Vfs*114 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- CIC | c.172del p.A58Pfs*147 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- CLSTN3 | c.1875del p.I626Sfs*20 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- COG1 | c.2628del p.F876Lfs*4 | Frame Shift Del (DEL) | VAF 6/69 reads (9%) | called by mutect2, pindel
- COL5A1 | c.2708del p.P903Lfs*171 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- CPNE7 | c.491del p.L164Yfs*2 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- CSDE1 | c.1236del p.K412Nfs*21 (on ENST00000358528 / NM_001007553.3; = p.K381Nfs*21 on NM_007158.6) | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | called by mutect2, pindel
- CUBN | c.2496del p.P833Lfs*67 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- CWC25 | c.429del p.K144Rfs*11 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- CXCR3 | c.154del p.D52Tfs*28 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- DBX1 | c.489del p.I164Sfs*57 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- DDX17 | c.488del p.G163Efs*20 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by pindel, varscan2
- DIAPH3 | c.2612del p.K871Rfs*17 (on ENST00000400324 / NM_001042517.2; = p.K608Rfs*17 on NM_030932.3) | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel
- DIO3 | c.285del p.D96Mfs*82 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- DNMT1 | c.2367del p.Q790Rfs*43 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- DRP2 | c.467del p.G156Afs*23 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- DUSP16 | c.1639del p.Q547Rfs*7 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- DYNC1LI2 | c.1327del p.S443Lfs*33 | Frame Shift Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- E2F3 | c.752del p.G251Afs*13 | Frame Shift Del (DEL) | VAF 8/93 reads (9%) | called by mutect2, pindel
- EID3 | c.741del p.I247Mfs*20 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- EIF2AK4 | c.193del p.T65Lfs*7 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- EIF5B | c.3360del p.K1120Nfs*18 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- EML3 | c.311del p.N104Mfs*78 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- EPB41L3 | c.2039del p.N680Mfs*42 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- ERBB4 | c.3530del p.N1177Mfs*27 | Frame Shift Del (DEL) | VAF 11/112 reads (10%) | called by mutect2, pindel
- ERMP1 | c.1477del p.C493Vfs*8 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- EXTL2 | c.101del p.G34Vfs*3 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- FAM71F2 | c.376del p.L126* | Frame Shift Del (DEL) | VAF 9/110 reads (8%) | called by mutect2, pindel
- FASTKD1 | c.578del p.L193Cfs*4 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- FGD1 | c.2281del p.C761Vfs*102 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- FGD1 | c.1103del p.L368* | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- FLYWCH1 | c.475del p.A159Pfs*10 (on ENST00000253928 / NM_001308068.2; = p.A158Pfs*10 on NM_020912.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- FOXJ1 | c.343del p.A115Pfs*6 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- GAB3 | c.1005del p.E335Dfs*14 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- GAS2L2 | c.1562del p.G521Vfs*18 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- GGPS1 | c.735del p.K245Nfs*10 | Frame Shift Del (DEL) | VAF 10/96 reads (10%) | called by pindel, varscan2
- GLDC | c.2304del p.I770Sfs*3 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- GLRB | c.74del p.K25Sfs*36 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- GMEB2 | c.1249del p.A417Rfs*41 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel
- GPC4 | c.354del p.K118Nfs*3 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- GSE1 | c.970del p.S324Lfs*14 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- HDAC7 | c.434del p.P145Qfs*15 (on ENST00000427332; = p.P184Qfs*15 on NM_015401.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/108 reads (10%) | called by mutect2, pindel
- HECTD4 | c.12011del p.P4004Lfs*104 | Frame Shift Del (DEL) | VAF 12/134 reads (9%) | called by mutect2, pindel
- HELZ2 | c.6285del p.K2096Sfs*15 (on ENST00000467148 / NM_001037335.2; = p.K1527Sfs*15 on NM_033405.3) | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- HELZ2 | c.3292del p.V1098Sfs*98 (on ENST00000467148 / NM_001037335.2; = p.V529Sfs*98 on NM_033405.3) | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel*
- HERC1 | c.9893del p.G3298Vfs*2 | Frame Shift Del (DEL) | VAF 10/108 reads (9%) | called by mutect2, pindel
- HGFAC | c.321del p.C108Afs*139 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- HIF3A | c.442del p.Q148Sfs*21 (on ENST00000377670 / NM_152795.4; = p.Q79Sfs*21 on NM_022462.4) | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel
- HMGXB4 | c.1353del p.D452Tfs*3 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by pindel, varscan2
- HNRNPA3 | c.586del p.C196Vfs*3 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- HR | c.1520del p.G507Efs*83 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- HS3ST1 | c.74del p.L25Qfs*112 | Frame Shift Del (DEL) | VAF 3/38 reads (8%) | called by mutect2, pindel
- IBSP | c.651del p.G218Efs*129 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- IFITM2 | c.129del p.V44* | Frame Shift Del (DEL) | VAF 9/109 reads (8%) | called by mutect2, pindel
- IFNG | c.167del p.L56* | Frame Shift Del (DEL) | VAF 11/75 reads (15%) | called by mutect2, pindel
- IL4R | c.2292del p.S765Lfs*48 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel
- ILKAP | c.714+1del p.X238_splice | Splice Site (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel
- IRF2 | c.135del p.W46Gfs*24 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel
- ITPR2 | c.4004del p.L1335* | Frame Shift Del (DEL) | VAF 3/22 reads (14%) | called by mutect2, pindel
- JPH2 | c.1313del p.L438Rfs*70 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- KAT6B | c.6042del p.Q2015Kfs*13 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- KATNAL1 | c.368del p.L123Rfs*8 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel
- KCNA1 | c.1453del p.C485Afs*8 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- KDM6A | c.4017del p.F1339Lfs*17 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel
- KIF24 | c.2966del p.L989Cfs*20 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- KIF5A | c.2589del p.K863Nfs*17 | Frame Shift Del (DEL) | VAF 9/96 reads (9%) | called by mutect2, pindel
- KIR3DL1 | c.696del p.K233Rfs*8 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- KLHL30 | c.583del p.S195Afs*6 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- KLRF1 | c.566del p.G189Vfs*4 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- KMT2E | c.260del p.N87Mfs*3 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- KRT18 | c.209del p.G70Vfs*18 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- LAMA2 | c.5862del p.K1954Nfs*10 | Frame Shift Del (DEL) | VAF 7/79 reads (9%) | called by mutect2, pindel
- LIPN | c.506del p.F169Sfs*10 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel
- LNX2 | c.1119del p.L374Wfs*8 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- LRRC41 | c.1319del p.L440Wfs*39 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by mutect2, pindel
- MAN2B1 | c.764-2del p.X255_splice | Splice Site (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- MAP3K11 | c.1723del p.E575Kfs*26 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- MARK2 | c.2040del p.E681Kfs*19 (on ENST00000402010 / NM_001039469.2; = p.E617Kfs*19 on NM_004954.5) | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- MED26 | c.1555del p.E519Rfs*25 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- MGAT3 | c.844del p.R282Gfs*171 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- MINDY3 | c.41del p.G14Afs*30 | Frame Shift Del (DEL) | VAF 7/83 reads (8%) | called by mutect2, pindel
- MIOX | c.736del p.V246Cfs*38 | Frame Shift Del (DEL) | VAF 7/80 reads (9%) | called by mutect2, pindel
- MIS18BP1 | c.2669+1del p.X890_splice | Splice Site (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- MISP | c.196del p.V66Cfs*56 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- MMRN1 | c.1869del p.V624Ffs*12 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- MORC2 | c.958del p.L320* (on ENST00000397641 / NM_001303256.3; = p.L258* on NM_014941.3) | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- MTMR6 | c.1302del p.F434Lfs*17 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- MTUS2 | c.2484del p.K828Nfs*66 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- MYH10 | c.1820del p.L607Cfs*28 | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel
- MYO18B | c.682del p.T228Lfs*4 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- MYO7B | c.3549del p.T1184Pfs*26 | Frame Shift Del (DEL) | VAF 10/93 reads (11%) | called by mutect2, pindel
- NAA16 | c.726del p.A243Pfs*8 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- NID1 | c.495del p.S167Afs*17 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- NUP210L | c.4929del p.V1645Ffs*5 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- NUP214 | c.3611del p.P1204Hfs*24 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- OAT | c.7del p.S3Pfs*3 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel
- OCA2 | c.353del p.P118Qfs*23 | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | called by mutect2, pindel
- OR4A5 | c.744del p.F248Lfs*21 | Frame Shift Del (DEL) | VAF 14/149 reads (9%) | called by mutect2, pindel
- OR7A10 | c.767del p.L256* | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel
- PCDH17 | c.250del p.L84Sfs*34 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- PCDHGA9 | c.1242del p.A415Pfs*8 | Frame Shift Del (DEL) | VAF 8/96 reads (8%) | called by mutect2, pindel
- PCNT | c.5644del p.Q1882Sfs*60 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- PDCD7 | c.1456del p.*486Sfs*17 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- PDLIM2 | c.924del p.G309Afs*10 (on ENST00000397760; = p.G559Afs*10 on NM_021630.6) | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- PGAP6 | c.2034del p.H679Tfs*34 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- PIDD1 | c.2391del p.R798Vfs*146 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- PIK3C2G | c.1083del p.I362Ffs*28 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel
- PIN4 | c.94del p.S32Vfs*32 (on ENST00000664196; = p.S7Vfs*32 on NM_006223.4) | Frame Shift Del (DEL) | VAF 10/150 reads (7%) | called by mutect2, pindel
- PINK1 | c.645del p.L216Wfs*5 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- PLD2 | c.644del p.G215Afs*26 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- PLEKHA5 | c.484del p.I162Lfs*23 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel
- PLEKHG3 | c.2690del p.K897Rfs*24 (on ENST00000394691; = p.K953Rfs*24 on NM_001308147.2) | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- PMFBP1 | c.463del p.E155Rfs*20 | Frame Shift Del (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel
- PNMA8A | c.777del p.K259Nfs*38 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by pindel, varscan2
- PPP4R3B | c.2499del p.D834Mfs*40 (on ENST00000616407 / NM_001122964.3; = p.D749Mfs*40 on NM_020463.4) | Frame Shift Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- PRPF8 | c.4653del p.Q1552Rfs*4 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- PRR12 | c.1510del p.Q504Sfs*46 (on ENST00000615927; = p.Q1325Sfs*46 on NM_020719.3) | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- PRUNE2 | c.6133del p.R2045Efs*28 | Frame Shift Del (DEL) | VAF 7/80 reads (9%) | called by mutect2, pindel
- PRX | c.3960del p.E1321Rfs*61 | Frame Shift Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- PTCH1 | c.3945del p.Y1316Tfs*56 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- PTCHD1 | c.379del p.V127Ffs*16 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- QRFPR | c.942del p.F314Lfs*22 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- RABL3 | c.278del p.F93Sfs*5 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- RAPGEF3 | c.1262del p.F421Sfs*3 (on ENST00000389212; = p.F379Sfs*3 on NM_006105.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- RBAK | c.804del p.K268Nfs*45 | Frame Shift Del (DEL) | VAF 6/80 reads (8%) | called by mutect2, pindel
- RBP3 | c.2527del p.L843* | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- RERE | c.2994del p.S999Pfs*9 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- RFX2 | c.342del p.A115Pfs*3 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- RIPK3 | c.187del p.A63Pfs*13 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- RP1L1 | c.1744del p.S582Hfs*3 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- RPGRIP1L | c.1711del p.D571Ifs*30 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- RPL21 | c.174del p.H58Qfs*19 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- RPL7L1 | c.127del p.A43Hfs*39 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- RPS6KA3 | c.1897del p.I633* | Frame Shift Del (DEL) | VAF 5/57 reads (9%) | called by mutect2, pindel
- RRP12 | c.3491del p.K1164Rfs*22 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- SAG | c.1188del p.K397Rfs*33 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel
- SALL2 | c.2147del p.G716Afs*62 | Frame Shift Del (DEL) | VAF 11/112 reads (10%) | called by mutect2, pindel
- SASH1 | c.818del p.K273Rfs*3 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- SCAF1 | c.1099del p.V367Sfs*6 | Frame Shift Del (DEL) | VAF 4/56 reads (7%) | called by mutect2, pindel
- SCAF1 | c.3028del p.E1010Rfs*97 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- SCAF4 | c.2510del p.G837Vfs*3 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- SCML2 | c.525del p.M176* | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel
- SEMA4C | c.2271del p.P759Lfs*36 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- SETX | c.1016del p.K339Sfs*2 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- SFXN3 | c.976del p.*326Efs*70 | Frame Shift Del (DEL) | VAF 5/52 reads (10%) | called by mutect2, pindel
- SH2D7 | c.1268del p.P423Qfs*58 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- SIGLEC1 | c.4108del p.D1370Tfs*73 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- SLC16A7 | c.1212del p.K404Nfs*12 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- SLC18A3 | c.213del p.T72Pfs*51 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- SLC22A3 | c.859del p.X287_splice | Splice Site (DEL) | VAF 4/40 reads (10%) | called by pindel, varscan2
- SLC25A12 | c.1613del p.P538Lfs*154 | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- SLC25A36 | c.94del p.T32Hfs*8 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel
- SLC2A4 | c.626del p.T209Kfs*36 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- SLC43A3 | c.231del p.S78Pfs*3 | Frame Shift Del (DEL) | VAF 13/158 reads (8%) | called by mutect2, pindel
- SMIM14 | c.124+2del p.X42_splice | Splice Site (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- SMTNL2 | c.484del p.A162Qfs*25 (on ENST00000389313 / NM_001114974.2; = p.A18Qfs*25 on NM_198501.3) | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- SPATA13 | c.667del p.D223Tfs*60 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- SPATA31E1 | c.1977del p.E659Dfs*50 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | called by mutect2, pindel
- SRMS | c.1184del p.P395Lfs*36 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- SRRM2 | c.1640del p.N547Ifs*161 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- STAT3 | c.2102-3del | Splice Region (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel
- STK38L | c.979del p.T327Hfs*9 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- SUPT16H | c.817del p.C273Vfs*18 | Frame Shift Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- SUV39H2 | c.776del p.N259Mfs*7 (on ENST00000354919 / NM_001193424.2; = p.N199Mfs*7 on NM_024670.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- SVEP1 | c.3366del p.C1123Vfs*104 | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | called by mutect2, pindel
- SYTL5 | c.271del p.E91Sfs*22 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- TACC2 | c.6697del p.T2233Rfs*13 (on ENST00000334433; = p.T311Rfs*13 on NM_006997.4) | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- TAS2R20 | c.846del p.N283Tfs*4 | Frame Shift Del (DEL) | VAF 9/93 reads (10%) | called by mutect2, pindel
- TBX10 | c.1107del p.L370Sfs*98 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- TCERG1 | c.3105del p.K1035Nfs*2 | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | called by mutect2, pindel
- TDP1 | c.359del p.N120Mfs*93 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- THBS2 | c.650_651del p.V217Gfs*16 | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | called by pindel, varscan2
- TICRR | c.4885del p.L1629Sfs*53 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- TIGD6 | c.205del p.R69Gfs*2 | Frame Shift Del (DEL) | VAF 12/138 reads (9%) | called by mutect2, pindel
- TLX1 | c.733del p.V245Sfs*167 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- TMEM176A | c.402del p.K134Nfs*51 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- TMPRSS11A | c.276del p.F92Lfs*2 | Frame Shift Del (DEL) | VAF 6/71 reads (8%) | called by mutect2, pindel
- TNFAIP2 | c.1360del p.L454Wfs*20 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- TNFAIP6 | c.75del p.H26Ifs*46 | Frame Shift Del (DEL) | VAF 6/61 reads (10%) | called by mutect2, pindel
- TNRC6B | c.788del p.P263Lfs*19 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- TOB1 | c.13del p.I5Sfs*3 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel
- TOM1L2 | c.1490del p.P497Qfs*63 (on ENST00000379504 / NM_001350333.2; = p.P447Qfs*63 on NM_001033551.3) | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- TP53I3 | c.79del p.E27Rfs*6 | Frame Shift Del (DEL) | VAF 6/73 reads (8%) | called by mutect2, pindel
- TRIM55 | c.1029del p.E344Kfs*11 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- TRIR | c.341del p.S114Tfs*12 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel
- TSTD2 | c.845del p.L282Yfs*10 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- TTL | c.853del p.L285Yfs*6 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- USP31 | c.3621del p.S1208Afs*8 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- USP39 | c.1283del p.K428Rfs*11 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- USP47 | c.2695del p.S899Vfs*50 (on ENST00000399455 / NM_001372095.1; = p.S811Vfs*50 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by mutect2, pindel
- USP9Y | c.3330del p.S1111Pfs*9 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- VAMP8 | c.34_53del p.R12* | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | called by mutect2, pindel, varscan2
- VCAM1 | c.1533del p.R512Efs*19 | Frame Shift Del (DEL) | VAF 11/102 reads (11%) | called by mutect2, pindel
- VDAC3 | c.77del p.M26Rfs*4 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- WASHC4 | c.2156del p.F719Sfs*11 | Frame Shift Del (DEL) | VAF 12/136 reads (9%) | called by mutect2, pindel
- XPOT | c.2282del p.L761Yfs*29 | Frame Shift Del (DEL) | VAF 12/142 reads (8%) | called by mutect2, pindel
- YARS2 | c.1399del p.R467Efs*6 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | called by pindel, varscan2
- ZC3H12C | c.372del p.C125Vfs*2 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- ZC3H4 | c.2302del p.A768Pfs*4 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- ZFAND5 | c.349del p.T117Qfs*115 | Frame Shift Del (DEL) | VAF 10/120 reads (8%) | called by mutect2, pindel
- ZFC3H1 | c.300del p.S102Afs*129 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- ZMIZ1 | c.359del p.P120Lfs*13 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, varscan2
- ZMYND15 | c.172del p.V58Cfs*43 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by pindel, varscan2
- ZNF136 | c.1386del p.R464Efs*5 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- ZNF232 | c.912del p.E304Dfs*99 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- ZNF292 | c.7633del p.R2545Gfs*14 | Frame Shift Del (DEL) | VAF 10/103 reads (10%) | called by mutect2, pindel
- ZNF333 | c.237del p.Q79Hfs*30 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- ZNF37A | c.1059del p.K353Nfs*78 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- ZNF462 | c.1928del p.N643Mfs*13 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel
- ZNF462 | c.5700del p.K1900Nfs*8 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- ZNF532 | c.842del p.K281Rfs*24 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by pindel, varscan2
- ZNF682 | c.1052del p.N351Tfs*11 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- ZNF92 | c.990del p.K330Nfs*4 (on ENST00000328747 / NM_152626.4; = p.K261Nfs*4 on NM_007139.4) | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- ADGRV1 | c.4803A>G p.G1601= | Silent (SNP) | VAF 62/324 reads (19%) | catalogued as COSV67979034; called by mutect2, varscan2
- CTNND2 | c.2025C>T p.I675= | Silent (SNP) | VAF 57/294 reads (19%) | catalogued as COSV58867196; called by mutect2, varscan2
- KCNC1 | c.402G>A p.A134= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV56391811; called by muse, mutect2, varscan2
- PDZD7 | c.1449C>T p.D483= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as rs778296630, COSV64645484; called by mutect2, varscan2
- RAI1 | c.4620C>A p.L1540= | Silent (SNP) | VAF 69/222 reads (31%) | catalogued as COSV55389419; called by mutect2, varscan2
- RAP1GDS1 | c.585T>C p.N195= (on ENST00000408927 / NM_001100427.2; = p.N196= on NM_021159.5) | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs1466530996, COSV52784471; called by mutect2, varscan2
- TCP11L1 | c.846C>T p.H282= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as rs145755006; called by mutect2, varscan2
- WIPF2 | c.1155T>C p.S385= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV60272351; called by mutect2, varscan2
- YTHDF2 | c.945A>G p.P315= | Silent (SNP) | VAF 30/320 reads (9%) | catalogued as COSV65722784; called by mutect2, varscan2
- ZNF761 | c.1428T>C p.R476= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV61887670; called by muse, varscan2
- ANK1 | c.5619+242del | Intron (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- C9orf163 | n.1425del | RNA (DEL) | VAF 4/36 reads (11%) | catalogued as rs1486343192; called by mutect2, pindel
- CHPF2 | c.*25del | 3'UTR (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- DDIT3 | c.-81+1195del | Intron (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- DMD | c.1331+2606del | Intron (DEL) | VAF 4/24 reads (17%) | catalogued as rs1262218953; called by pindel, varscan2
- EXOC3 | chr5:442473 del C | 5'Flank (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- HAUS6 | c.1377-104del | Intron (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- LPCAT3 | c.-2del | 5'UTR (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- PRR12 | c.52-208del | Intron (DEL) | VAF 3/30 reads (10%) | catalogued as COSV69816550, COSV69817814; called by mutect2, pindel
- SLC4A4 | c.*5del | 3'UTR (DEL) | VAF 10/100 reads (10%) | called by mutect2, pindel
- SS18L1 | c.146+74del | Intron (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel
- SSPOP | n.9697del | RNA (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- WSCD1 | c.*4del | 3'UTR (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
